Somatic mutation profile of tumor specimen 0DF2BO from CCDI case PBBMTJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.9 years (5,083 days).
Specimen 0DF2BO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5628476b-4239-4aa2-80ac-30979bf7a3ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF2BY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d61dbc79-8ab0-41ff-bd21-f31e196e06dd

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Ins 2, Frame Shift Del 2, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, mutect2
- C2CD2L | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 146/330 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs374518930; called by muse, mutect2, varscan2
- TPST2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs371365617; called by muse, mutect2, varscan2
- ARHGEF12 | c.2107A>G p.T703A | Missense Mutation (SNP) | VAF 41/768 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- DNAAF4 | c.159_160insA p.Y54Ifs*7 | Frame Shift Ins (INS) | VAF 42/268 reads (16%) | called by mutect2, varscan2
- KIF23 | c.2686G>T p.E896* (on ENST00000260363; = p.E792* on NM_004856.7) | Nonsense Mutation (SNP) | VAF 76/632 reads (12%) | called by muse, mutect2, varscan2
- MACC1 | c.1747del p.E583Kfs*4 | Frame Shift Del (DEL) | VAF 135/530 reads (25%) | called by mutect2, varscan2
- RABIF | c.33_34dup p.S12Cfs*38 | Frame Shift Ins (INS) | VAF 62/234 reads (26%) | called by mutect2, varscan2
- ZNF808 | c.1352del p.G451Efs*85 | Frame Shift Del (DEL) | VAF 2/12 reads (17%) | called by mutect2, varscan2
- CABP2 | c.153C>A p.L51= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- PIP4K2A | c.429C>A p.I143= | Silent (SNP) | VAF 116/528 reads (22%) | catalogued as COSV60540098; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
